Somatic mutation profile of tumor specimen 0DT69F from CCDI case PBCJBB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,651 days).
Specimen 0DT69F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9bea8e0-d948-4325-affb-f8d1f6eebd43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT69B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/183a09bc-9d58-4946-92e3-16a54e64e87d

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.3865C>T p.R1289C (on ENST00000611781; = p.R1233C on NM_052997.2) | Missense Mutation (SNP) | VAF 80/2251 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs533966003, COSV64624204; called by muse, mutect2
- CNTNAP5 | c.2359+1G>A p.X787_splice | Splice Site (SNP) | VAF 91/1164 reads (8%) | catalogued as rs768145367, COSV101443175; called by muse, mutect2
- IQSEC3 | c.1069C>T p.R357W (on ENST00000538872 / NM_001170738.2; = p.R54W on NM_015232.1) | Missense Mutation (SNP) | VAF 113/443 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs868934519, COSV58283765; called by muse, mutect2, varscan2
- MYH7B | c.5662G>A p.V1888M | Missense Mutation (SNP) | VAF 59/697 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.177); catalogued as rs200404804; called by muse, mutect2
- PIK3R3 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 52/714 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); catalogued as rs771670552; called by muse, mutect2
- RIMBP2 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 97/933 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs549158714, COSV55469326, COSV55475139, COSV55479677; called by muse, mutect2, varscan2
- BCL11B | c.2119G>A p.V707M (on ENST00000357195 / NM_001282237.2; = p.V636M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- GPR37L1 | c.1001G>C p.R334P | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HIC2 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2
- ZSWIM6 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 106/1344 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMTA1 | c.4783C>A p.R1595= | Silent (SNP) | VAF 77/1397 reads (6%) | catalogued as COSV100346816; called by muse, mutect2
- FAM171A1 | c.183C>T p.A61= | Silent (SNP) | VAF 118/801 reads (15%) | catalogued as rs745904759; called by muse, mutect2, varscan2
